Somatic mutation profile of tumor specimen 2a237fd4-f966-4563-bab1-61dbd7 (aliquot 2a237fd4-f966-4563-bab1-61dbd7_D6) from CPTAC case 01OV047, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIB.
Specimen 2a237fd4-f966-4563-bab1-61dbd7: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b9072c31-fffd-4f4c-a78e-5322ba3252ec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 38fd7771-eaa7-4d4c-aea2-00fe7a (Blood Derived Normal), aliquot 38fd7771-eaa7-4d4c-aea2-00fe7a_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/93f67dc3-b6cd-47e9-9bd1-1afb36604c28

The open-access MAF lists 37 somatic variants for this specimen: 26 protein-altering or splice-affecting, 5 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 5, RNA 3, 3'UTR 2, 3'Flank 1, In Frame Del 1, Nonsense Mutation 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGAP30 | c.1189C>T p.R397W | Missense Mutation (SNP) | VAF 79/305 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); catalogued as rs776609904, COSV63515921; called by muse, mutect2, varscan2
- CILP2 | c.2548G>A p.D850N | Missense Mutation (SNP) | VAF 76/319 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.707); catalogued as rs1256475950; called by muse, mutect2, varscan2
- CNGA1 | c.1682T>G p.I561S | Missense Mutation (SNP) | VAF 47/198 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs778592209; called by muse, mutect2, varscan2
- OTOF | c.169G>A p.D57N | Missense Mutation (SNP) | VAF 87/367 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs754784459; called by muse, mutect2, varscan2
- SKOR2 | c.56G>A p.S19N | Missense Mutation (SNP) | VAF 103/307 reads (34%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.098); catalogued as rs1485935707; called by muse, mutect2, varscan2
- STAU1 | c.292C>T p.R98W (on ENST00000371856 / NM_001319135.1; = p.R17W on NM_004602.3) | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.849); catalogued as COSV99049331; called by muse, mutect2, varscan2
- THSD1 | c.802G>A p.V268I | Missense Mutation (SNP) | VAF 69/226 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs201109452; called by muse, mutect2, varscan2
- ABCA13 | c.8585C>A p.T2862K | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.549); called by muse, mutect2
- ACOT12 | c.895A>T p.T299S | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- ALDH1L1 | c.618G>T p.K206N | Missense Mutation (SNP) | VAF 145/192 reads (76%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- CBLL1 | c.1408C>T p.P470S | Missense Mutation (SNP) | VAF 50/201 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DNAH11 | c.6710del p.L2237Pfs*20 | Frame Shift Del (DEL) | VAF 12/55 reads (22%) | called by mutect2, pindel, varscan2
- DNAH17 | c.12358G>A p.V4120I | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ERMARD | c.1046G>C p.G349A | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- FAT1 | c.184_204del p.Y62_W68del | In Frame Del (DEL) | VAF 61/322 reads (19%) | called by mutect2, pindel, varscan2
- MOAP1 | c.292C>A p.P98T | Missense Mutation (SNP) | VAF 104/287 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- OTOF | c.3133G>A p.A1045T (on ENST00000272371 / NM_194248.3; = p.A298T on NM_004802.4) | Missense Mutation (SNP) | VAF 229/597 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- P2RX6 | c.390C>T p.H130= | Splice Region (SNP) | VAF 11/34 reads (32%) | called by muse, mutect2, varscan2
- PRAMEF15 | c.304C>T p.L102F | Missense Mutation (SNP) | VAF 82/266 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- PRKCZ | c.925A>T p.S309C | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, varscan2
- PRKCZ | c.926G>C p.S309T | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.013); called by muse, varscan2
- PRRC2A | c.4858C>T p.R1620* | Nonsense Mutation (SNP) | VAF 54/210 reads (26%) | called by muse, mutect2, varscan2
- SARM1 | c.2111C>T p.S704F | Missense Mutation (SNP) | VAF 58/193 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- SCAF4 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- TCF24 | c.330G>T p.E110D | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, varscan2
- ZHX3 | c.2198G>C p.R733T | Missense Mutation (SNP) | VAF 60/314 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- NTSR2 | c.546G>T p.T182= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV100183812, COSV100183865; called by muse, mutect2
- PRKCZ | c.927C>T p.S309= | Silent (SNP) | VAF 32/100 reads (32%) | called by muse, varscan2
- RCAN3 | c.489G>A p.A163= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as rs749944522; called by muse, mutect2
- UGT2B4 | c.27T>G p.L9= | Silent (SNP) | VAF 9/31 reads (29%) | called by muse, mutect2, varscan2
- VPS13B | c.1134A>G p.Q378= | Silent (SNP) | VAF 24/96 reads (25%) | catalogued as rs1189439309; called by muse, mutect2, varscan2
- EMC3-AS1 | n.927C>A | RNA (SNP) | VAF 6/76 reads (8%) | called by muse, mutect2
- IL1RAP | chr3:190656165 G>A | 3'Flank (SNP) | VAF 91/313 reads (29%) | catalogued as rs773201140, COSV99300429; called by muse, mutect2, varscan2
- LINC01148 | n.336del | RNA (DEL) | VAF 4/24 reads (17%) | called by mutect2, pindel
- LRRC37A6P | n.2341C>T | RNA (SNP) | VAF 109/418 reads (26%) | catalogued as rs1437417138; called by muse, mutect2, varscan2
- MTPN | c.*2612A>T | 3'UTR (SNP) | VAF 29/102 reads (28%) | called by muse, mutect2, varscan2
- NBEAL2 | c.*186C>G | 3'UTR (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2, varscan2
